Somatic mutation profile of tumor specimen 0DPE9K from CCDI case PBCDEY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 18.0 years (6,562 days).
Specimen 0DPE9K: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07c0d54f-fb5f-47d4-aa15-77b9a582ddaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPE93 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f1584df-ec17-4481-b450-7b1a568cf2af

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COX17 | c.34C>G p.P12A | Missense Mutation (SNP) | VAF 34/325 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCER2 | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC2 | c.4020G>A p.S1340= | Silent (SNP) | VAF 14/400 reads (4%) | catalogued as rs993156242; called by muse, mutect2
